Somatic mutation profile of tumor specimen TCGA-N9-A4Q8-01A (aliquot TCGA-N9-A4Q8-01A-31D-A28R-08) from TCGA case TCGA-N9-A4Q8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 69.0 years (25,185 days).
Specimen TCGA-N9-A4Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 535a7df1-3cb5-4939-8fdd-cb27af1f9f8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4Q8-11A (Solid Tissue Normal), aliquot TCGA-N9-A4Q8-11A-11D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbba1c2-7305-4dea-b212-23bb7ceb4c53

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 30/34 reads (88%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALAS2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58189668; called by muse, mutect2, varscan2
- BCLAF1 | c.2387G>C p.R796P | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50357321, COSV50357874; called by muse, mutect2, varscan2
- COL4A4 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769191749; called by muse, mutect2, varscan2
- CST2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs778438809; called by muse, mutect2, varscan2
- EPPK1 | c.6070C>T p.R2024W | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782809770; called by muse, mutect2
- FCRL5 | c.192A>T p.K64N | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.262); catalogued as COSV62518804; called by muse, mutect2, varscan2
- GART | c.2474T>C p.I825T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771014442; called by muse, mutect2, varscan2
- GFOD1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1320865293; called by muse, varscan2
- GIMAP1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56189041; called by muse, mutect2, varscan2
- HLA-DRA | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs1407197550, COSV66622563; called by muse, mutect2
- HMCN2 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs187325867; called by muse, mutect2, varscan2
- HTR1E | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1005765975, COSV59507514; called by muse, mutect2, varscan2
- HUWE1 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM152728, COSV53364621; called by muse, mutect2, varscan2
- IGFBPL1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV66618010; called by muse, mutect2, varscan2
- NCOR2 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656981; called by muse, mutect2, varscan2
- PKDREJ | c.4913C>T p.T1638M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs370600000; called by mutect2, varscan2
- SPOP | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 111/120 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100753535, COSV61653007; called by muse, varscan2
- TNFAIP3 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs201074555, COSV52800454; called by muse, mutect2, varscan2
- ZNF804B | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769833252; called by muse, mutect2, varscan2
- ANXA13 | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL2L11 | c.561dup p.R188Tfs*77 (on ENST00000393256 / NM_138621.5; = p.R128Tfs*77 on NM_006538.5) | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- BRWD1 | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CAPN15 | c.2146del p.R716Gfs*100 | Frame Shift Del (DEL) | VAF 56/130 reads (43%) | called by mutect2, pindel, varscan2
- CASZ1 | c.2287A>T p.S763C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CEP128 | c.2233A>G p.N745D | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- FMN2 | c.3852G>C p.K1284N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMIP | c.2564C>G p.S855* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- GTF2H1 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- KIF26B | c.5132G>A p.G1711D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LCP1 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- LILRA4 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PPP1R3A | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- PRPF4B | c.22T>G p.S8A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPH3A | c.95_99del p.G32Vfs*9 (on ENST00000389385 / NM_001143854.2; = p.G28Vfs*9 on NM_014954.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | called by mutect2, pindel, varscan2
- RRM1 | c.69_70del p.K24Afs*11 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1116dup p.A373Sfs*16 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by mutect2, varscan2
- TOX | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRPM4 | c.3241G>A p.V1081I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZMAT4 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 239/272 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- C11orf1 | c.186T>C p.N62= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1182496107; called by mutect2, varscan2
- EIF3I | c.774C>A p.T258= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- FAM24B | c.264C>T p.C88= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs758502475, COSV59026481; called by muse, mutect2, varscan2
- HHIP | c.768T>C p.P256= | Silent (SNP) | VAF 62/140 reads (44%) | called by muse, mutect2, varscan2
- ITGA5 | c.1002C>T p.D334= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as rs553785363; called by muse, mutect2, varscan2
- OR10A7 | c.495C>T p.A165= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- PKNOX2 | c.1371G>A p.T457= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs1196044043; called by muse, mutect2, varscan2
- SLC4A7 | c.570A>T p.V190= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- SULT1C3 | c.261C>T p.H87= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs201163943, COSV100227477; called by muse, mutect2, varscan2
- TMPRSS6 | c.1929C>T p.S643= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, varscan2
- VIRMA | c.3915T>A p.G1305= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, varscan2
